Somatic mutation profile of tumor specimen 0DK0AM from CCDI case PBBXMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Tail of pancreas; Age at diagnosis: 11.1 years (4,059 days).
Specimen 0DK0AM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80460551-aa97-40b5-aeb6-e331178be9e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK0AP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ae5e8ef-e5c0-4bf3-96f8-6598eafd35e7

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT25 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 288/605 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1467844178; called by muse, mutect2, varscan2
- PITRM1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 167/448 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56533712; called by muse, mutect2, varscan2
- SENP3 | c.561C>G p.D187E | Missense Mutation (SNP) | VAF 136/256 reads (53%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.054); catalogued as rs753586901; called by muse, mutect2, varscan2
- ADPRHL1 | c.2500A>G p.T834A | Missense Mutation (SNP) | VAF 140/329 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANO5 | c.385T>G p.Y129D | Missense Mutation (SNP) | VAF 265/599 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- DNAJC5B | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 241/493 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBN2 | c.6321T>A p.N2107K | Missense Mutation (SNP) | VAF 110/600 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLLN | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 138/266 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CILP2 | c.2460G>A p.P820= | Silent (SNP) | VAF 137/322 reads (43%) | catalogued as rs1053343182; called by muse, mutect2, varscan2
- STAB1 | c.2235+39A>C | Intron (SNP) | VAF 126/262 reads (48%) | called by muse, mutect2, varscan2
